Somatic mutation profile of tumor specimen BA2820D (aliquot aq-BA2820D) from BEATAML1.0 case 2542, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.2 years (26,741 days).
Specimen BA2820D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23cd5c28-ee3e-49aa-8993-250b6496c28b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2388D (Solid Tissue Normal), aliquot aq-BA2388D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1ec7e65-7d65-4502-b6e1-a8cbabaa948d

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.26C>A p.P9H | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); called by muse, mutect2
- CD1E | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- CEBPG | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); called by muse, mutect2
- HMGXB3 | c.2585C>A p.A862D (on ENST00000613459; = p.A616D on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- IQGAP1 | c.952C>A p.Q318K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2
- TMEM67 | chr8:93754861 C>A | 5'Flank (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
